Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A83K, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A83K-01A (Primary Tumor).

[page 1 of 4]
MRN
Name
Encounter NumberGender
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
StatusTime Received
Order Number

Results

Source of Specimen

- A. TISSUE ANTERIOR TO PROSTATE-
B. PROSTATE, SEMINAL VESICLES AND VAS DEFERENS-

FINAL DIAGNOSIS:

- A. TISSUE ANTERIOR TO PROSTATE-
FIBROFATTY TISSUE WITH NO TUMOR SEEN.
B. PROSTATE, SEMINAL VESICLES AND VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE (see synoptic report below).

Final
GCE ICD-3
Adenocarcinoma, acinar 8140/3
path Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
9/21/24/13

SYNOPTIC REPORT:

ADENOCARCINOMA OF PROSTATE

NO EXTRAPROSTATIC EXTENSION SEEN

TUMOR SITE: BILATERAL

SPECIMEN TYPE: RADICAL PROSTATECTOMY

WEIGHT: 40 GRAMS

SIZE: 4.5 x 4 x 4 CM

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 3 = 6/10

SEVERITY IN EXTENT OF TUMOR: 3 / 5

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue)

[page 2 of 4]
involvement).

TNM STAGE: pT2c, pNX, pMX

LYMPHATIC (SMALL VESSEL) INVASION: NOT FOUND

PERINEURAL INVASION: PRESENT

NO TUMOR SEEN IN SEMINAL VESICLES

NO TUMOR SEEN AT SPECIMEN MARGINS

Case Clinical Information
PROSTATE CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "tissue anterior to prostate" are multiple yellow-tan adipose tissue fragments measuring 3 x 2 cm. The specimen is entirely submitted in A1-A3.

B. Received in formalin labeled with the patient's name and "prostate, seminal vesicles and vas deferens" is a radical prostatectomy specimen which includes a 40 gram prostate gland with attached seminal vesicle and vas deferens. The prostate gland measures 4.5 x 4 x 4 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 3 x 1.5 cm. The right vas measures 2 x 0.4 cm. The left seminal vesicle measures 2 x 1.5 cm. The left vas measures 2 x 0.4 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen and sectioned from anterior to posterior following the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. Representative sections submitted as follows: inferior prostate demonstrating apical margin submitted entirely anterior to posterior in B1-B5 ; bladder resection margin shaved, perpendicularly sectioned and submitted in B6-B7; complete section of mid gland anterior B8-B9; posterior B10-B11; complete section of upper third of gland, anterior B12-B13; posterior B14-B15; remainder of the posterior gland entirely submitted in B16-B22; right seminal vesicle and vas deferens B23; left

[page 3 of 4]
seminal vesicle and vas deferens B24. 85% of the specimen is represented.

Procedure

A. AA ROUTINE H&E X1 BLOCK.1
H&E X1
A. AA ROUTINE H&E X1 BLOCK.2
H&E X1
A. AA ROUTINE H&E X1 BLOCK.3
H&E X1
B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
B. AA ROUTINE H&E X1 BLOCK.3
H&E X1
B. AA ROUTINE H&E X1 BLOCK.4
H&E X1
B. AA ROUTINE H&E X1 BLOCK.5
H&E X1
B. AA ROUTINE H&E X1 BLOCK.6
H&E X1
B. AA ROUTINE H&E X1 BLOCK.7
H&E X1
B. AA ROUTINE H&E X1 BLOCK.8
H&E X1
B. AA ROUTINE H&E X1 BLOCK.9
H&E X1
B. AA ROUTINE H&E X1 BLOCK.10
H&E X1
B. AA ROUTINE H&E X1 BLOCK.11
H&E X1
B. AA ROUTINE H&E X1 BLOCK.12
H&E X1
B. AA ROUTINE H&E X1 BLOCK.13
H&E X1
B. AA ROUTINE H&E X1 BLOCK.14
H&E X1
B. AA ROUTINE H&E X1 BLOCK.15
H&E X1
B. AA ROUTINE H&E X1 BLOCK.16
H&E X1
B. AA ROUTINE H&E X1 BLOCK.17
H&E X1

[page 4 of 4]
B. AA ROUTINE H&E X1 BLOCK.18
H&E X1
B. AA ROUTINE H&E X1 BLOCK.19
H&E X1
B. AA ROUTINE H&E X1 BLOCK.20
H&E X1
B. AA ROUTINE H&E X1 BLOCK.21
H&E X1
B. AA ROUTINE H&E X1 BLOCK.22
H&E X1
B. AA ROUTINE H&E X1 BLOCK.23
H&E X1
B. AA ROUTINE H&E X1 BLOCK.24
H&E X1

Source: NCI Genomic Data Commons file 06adfd2d-1b04-48ac-9b27-992f18eade13 (TCGA-J4-A83K.B03E6C45-550E-4657-9292-75D7BB058D2A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).